Somatic mutation profile of tumor specimen ALCH-B25U-TTP1-A (aliquot ALCH-B25U-TTP1-A-1-0-D-A774-36) from ALCHEMIST case ALCH-B25U, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.5 years (23,575 days).
Specimen ALCH-B25U-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75e79850-4604-48ee-8f6d-ab9c58895ec5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B25U-NB1-A (Blood Derived Normal), aliquot ALCH-B25U-NB1-A-1-0-D-A774-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca1c82a8-cd45-4c46-befe-9e0c435478b1

The open-access MAF lists 208 somatic variants for this specimen: 150 protein-altering or splice-affecting, 40 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 135, Silent 40, Nonsense Mutation 9, RNA 7, Intron 5, Splice Site 4, 3'UTR 4, 5'Flank 1, Splice Region 1, 5'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 79/574 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2539A>G p.I847V | Missense Mutation (SNP) | VAF 47/529 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.019); catalogued as rs1432480917; called by muse, mutect2
- ACSL6 | c.633G>C p.E211D (on ENST00000379240; = p.E236D on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/193 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV57301844; called by muse, mutect2
- AK7 | c.1411A>G p.M471V | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as rs754143982; called by muse, mutect2
- AMER1 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 26/298 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV57656318; called by muse, mutect2
- ASB10 | c.785C>T p.S262F (on ENST00000420175 / NM_001142459.2; = p.S247F on NM_080871.4) | Missense Mutation (SNP) | VAF 37/317 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as rs1202518034; called by muse, mutect2, varscan2
- ASXL3 | c.6592C>A p.Q2198K | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV52466217; called by muse, mutect2
- ATXN2 | c.3596C>A p.A1199E (on ENST00000550104; = p.A1039E on NM_002973.4) | Missense Mutation (SNP) | VAF 56/744 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57984655; called by muse, mutect2
- BTBD1 | c.526A>T p.R176W | Missense Mutation (SNP) | VAF 45/391 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV99915816; called by muse, mutect2, varscan2
- C6orf89 | c.223G>T p.A75S (on ENST00000373685; = p.A82S on NM_152734.4) | Missense Mutation (SNP) | VAF 48/586 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV100769818; called by muse, mutect2
- CDHR1 | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 40/518 reads (8%) | catalogued as COSV60564473, COSV60564846; called by muse, mutect2
- CDKL5 | c.2518C>G p.R840G | Missense Mutation (SNP) | VAF 42/676 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as COSV66111770; called by muse, mutect2
- CDR1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100983421; called by muse, mutect2
- EBF1 | c.703C>G p.H235D | Missense Mutation (SNP) | VAF 54/609 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58177213; called by muse, mutect2
- EFCAB8 | c.947A>G p.Y316C | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs957488709; called by muse, mutect2
- ESR1 | c.939C>A p.D313E | Missense Mutation (SNP) | VAF 54/672 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148773555; called by muse, mutect2
- GALNT13 | c.526C>A p.P176T | Missense Mutation (SNP) | VAF 42/558 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV67218941; called by muse, mutect2
- GNAQ | c.943G>C p.D315H | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV54108620, COSV54112513; called by muse, mutect2, varscan2
- GOLGB1 | c.4731G>T p.E1577D | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.297); catalogued as rs749289732; called by muse, mutect2
- GPR174 | c.558G>T p.M186I | Missense Mutation (SNP) | VAF 31/614 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV52134376; called by muse, mutect2
- GRIK2 | c.1716G>T p.L572F | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV100028422; called by muse, mutect2
- GRIN2C | c.506C>T p.T169I | Missense Mutation (SNP) | VAF 22/223 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV53112777; called by muse, mutect2
- LIG3 | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs536339528; called by muse, mutect2
- LRRC4C | c.1438C>A p.P480T | Missense Mutation (SNP) | VAF 18/223 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV53440703; called by muse, mutect2
- LRRIQ1 | c.3377+1G>T p.X1126_splice | Splice Site (SNP) | VAF 38/514 reads (7%) | catalogued as COSV67835708; called by muse, mutect2
- NEU2 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs201616110; called by muse, mutect2
- NPAP1 | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.777); catalogued as rs1168070065; called by muse, mutect2, varscan2
- NPR3 | c.526C>A p.R176S | Missense Mutation (SNP) | VAF 18/269 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54085059; called by muse, mutect2
- OR2AK2 | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV63552213; called by muse, mutect2
- P2RY4 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs765017183; called by muse, mutect2
- PLA2G2F | c.439A>T p.T147S | Missense Mutation (SNP) | VAF 18/199 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.391); catalogued as COSV100907889; called by muse, mutect2
- PRMT8 | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 42/600 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54218320; called by muse, mutect2
- RBAK | c.478A>G p.T160A | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100806709; called by muse, mutect2
- RIMS2 | c.1001G>A p.R334Q (on ENST00000666250 / NM_001348490.2; = p.R142Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/683 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs769876416, COSV51676312; called by muse, mutect2
- SAMD3 | c.682C>A p.R228S | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs201988282, COSV100931800, COSV63712931; called by muse, mutect2
- SI | c.3994G>A p.A1332T | Missense Mutation (SNP) | VAF 35/464 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs768951450; called by muse, mutect2
- SLC30A8 | c.1060C>A p.P354T | Missense Mutation (SNP) | VAF 21/404 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV69968818; called by muse, mutect2
- SLC34A2 | c.514T>G p.S172A | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.047); catalogued as rs1323934956; called by muse, mutect2
- SP8 | c.239C>T p.A80V (on ENST00000361443 / NM_198956.4; = p.A98V on NM_182700.6) | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.063); catalogued as rs1403710740; called by muse, mutect2
- SPEF2 | c.1819G>A p.V607I | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV61547277; called by muse, mutect2
- SRRM2 | c.2441G>T p.R814L | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); catalogued as rs375822528, COSV57076898; called by muse, mutect2, varscan2
- STK11 | c.130A>T p.K44* | Nonsense Mutation (SNP) | VAF 39/414 reads (9%) | catalogued as CM066241, COSV58823222; called by muse, mutect2
- TDP1 | c.1183G>T p.V395L | Missense Mutation (SNP) | VAF 31/506 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV59642927; called by muse, mutect2
- TRPM3 | c.4450C>A p.P1484T (on ENST00000357533 / NM_001366142.2; = p.P1339T on NM_020952.6) | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.005); catalogued as COSV62594706; called by muse, mutect2
- TTN | c.7444G>A p.D2482N (on ENST00000591111; = p.D2436N on NM_003319.4) | Missense Mutation (SNP) | VAF 36/632 reads (6%) | PolyPhen benign (0.039); catalogued as COSV59862290, COSV59883227; called by muse, mutect2
- ZNF431 | c.1607G>T p.R536I | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs369263368, COSV60672202; called by muse, mutect2
- ADAMTS6 | c.2563A>T p.T855S | Missense Mutation (SNP) | VAF 71/948 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.088); called by muse, mutect2
- AGGF1 | c.319T>G p.F107V | Missense Mutation (SNP) | VAF 9/234 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- AHRR | c.1288C>G p.P430A | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AJUBA | c.531G>T p.L177F | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ALG11 | c.463G>T p.G155* | Nonsense Mutation (SNP) | VAF 30/393 reads (8%) | called by muse, mutect2
- ANKRD60 | c.868A>G p.I290V | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.033); called by muse, mutect2
- ARHGAP29 | c.170A>T p.H57L | Missense Mutation (SNP) | VAF 25/338 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2
- ASXL1 | c.3752A>T p.Q1251L | Missense Mutation (SNP) | VAF 60/850 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.462); called by muse, mutect2
- CADPS2 | c.2616G>T p.L872F | Missense Mutation (SNP) | VAF 35/281 reads (12%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- CALML4 | c.14A>G p.H5R | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.01); called by muse, mutect2
- CCDC136 | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 48/529 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CCDC158 | c.2347A>G p.T783A | Missense Mutation (SNP) | VAF 30/440 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.069); called by muse, mutect2
- CDHR5 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.983); called by muse, mutect2
- CERS6 | c.1105A>C p.S369R | Missense Mutation (SNP) | VAF 32/412 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.172); called by muse, mutect2
- CFAP46 | c.7498C>G p.Q2500E | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.82); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CNGB1 | c.2663C>A p.A888D | Missense Mutation (SNP) | VAF 32/464 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2
- COL11A2 | c.1321G>A p.G441R (on ENST00000341947 / NM_080680.3; = p.G334R on NM_080679.2) | Missense Mutation (SNP) | VAF 44/425 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD3 | c.7786T>A p.C2596S (on ENST00000297405 / NM_001363185.1; = p.C2492S on NM_052900.3) | Missense Mutation (SNP) | VAF 43/598 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- CSMD3 | c.7549+1G>T p.X2517_splice (on ENST00000297405 / NM_001363185.1; = p.X2413_splice on NM_052900.3) | Splice Site (SNP) | VAF 18/232 reads (8%) | called by muse, mutect2
- DAGLA | c.1582A>T p.R528W | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DCP1B | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 22/303 reads (7%) | called by muse, mutect2
- DCSTAMP | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- DDX20 | c.2433G>A p.M811I | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.086); called by muse, mutect2
- DDX53 | c.1198G>C p.D400H | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DOCK11 | c.871+2T>A p.X291_splice | Splice Site (SNP) | VAF 5/98 reads (5%) | called by muse, mutect2
- DOCK2 | c.2711C>A p.T904N | Missense Mutation (SNP) | VAF 43/362 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPF3 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 35/580 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2
- DSCAML1 | c.3523C>A p.P1175T (on ENST00000321322; = p.P1115T on NM_020693.4) | Missense Mutation (SNP) | VAF 31/463 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- ELFN1 | c.1178C>T p.T393I | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- ELP5 | c.815C>A p.P272H | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FLRT2 | c.863T>C p.L288P | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FRY | c.3745A>T p.R1249W | Missense Mutation (SNP) | VAF 28/397 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- HMCN1 | c.6652T>A p.C2218S | Missense Mutation (SNP) | VAF 38/574 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HMCN2 | c.11696G>T p.R3899L | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2
- HOXC10 | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0.013); called by muse, mutect2
- IGHV3-53 | c.326C>A p.T109K | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.593); called by muse, mutect2
- KCP | c.2155+3G>T | Splice Region (SNP) | VAF 24/402 reads (6%) | called by muse, mutect2
- KDM5A | c.1895C>T p.A632V | Missense Mutation (SNP) | VAF 35/376 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2
- KIAA1109 | c.14790A>T p.E4930D | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- LRRTM1 | c.996C>A p.F332L | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2
- MAGEA4 | c.585G>T p.Q195H | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- MAGEC3 | c.1812C>A p.Y604* | Nonsense Mutation (SNP) | VAF 14/384 reads (4%) | called by muse, mutect2
- MGAT4C | c.313C>A p.L105I | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- MORC3 | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- MPDU1 | c.740A>C p.Q247P | Missense Mutation (SNP) | VAF 50/610 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2
- MPPED1 | c.663C>A p.N221K | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2
- MRAP2 | c.378G>C p.L126F | Missense Mutation (SNP) | VAF 22/439 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.299); called by muse, mutect2
- MROH7 | c.3883C>A p.P1295T | Missense Mutation (SNP) | VAF 37/439 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.342); called by muse, mutect2
- MYH9 | c.5669A>T p.N1890I | Missense Mutation (SNP) | VAF 19/261 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.326); called by muse, mutect2
- MYO7A | c.4337A>C p.Q1446P | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, varscan2
- NECAB2 | c.613C>A p.P205T | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2
- NELL1 | c.1399A>T p.I467F | Missense Mutation (SNP) | VAF 34/400 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.624); called by muse, mutect2
- NELL2 | c.1951C>A p.Q651K | Missense Mutation (SNP) | VAF 52/620 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); called by muse, mutect2
- NKX1-1 | c.788C>A p.A263E | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.099); called by muse, mutect2
- NPAP1 | c.639C>A p.Y213* | Nonsense Mutation (SNP) | VAF 20/219 reads (9%) | called by muse, mutect2
- NPSR1 | c.569T>A p.L190Q | Missense Mutation (SNP) | VAF 62/662 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); called by muse, mutect2
- NPY2R | c.679T>A p.L227M | Missense Mutation (SNP) | VAF 56/662 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.56); called by muse, mutect2
- NRG1 | c.221C>A p.A74D (on ENST00000523534; = p.A221D on NM_013962.2) | Missense Mutation (SNP) | VAF 28/293 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.103); called by muse, mutect2
- NUTM2D | c.50C>G p.S17* | Nonsense Mutation (SNP) | VAF 63/1650 reads (4%) | called by muse, mutect2
- NXPE2 | c.230C>A p.P77Q | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.091); called by muse, mutect2
- OR10Q1 | c.548T>A p.L183H | Missense Mutation (SNP) | VAF 40/595 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- OR10R2 | c.27C>A p.Y9* | Nonsense Mutation (SNP) | VAF 22/186 reads (12%) | called by muse, mutect2
- OR2L2 | c.368T>A p.V123E | Missense Mutation (SNP) | VAF 41/508 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2
- OR2V2 | c.809G>C p.S270T | Missense Mutation (SNP) | VAF 21/366 reads (6%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.815); called by muse, mutect2
- OR52E6 | c.736A>G p.I246V | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.1); called by muse, mutect2
- OTUD7B | c.844G>C p.G282R | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- OXCT2 | c.824A>T p.Y275F | Missense Mutation (SNP) | VAF 16/307 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2
- P2RY4 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PEX7 | c.690T>G p.N230K | Missense Mutation (SNP) | VAF 47/802 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.122); called by muse, mutect2
- PNCK | c.807-1G>T p.X269_splice (on ENST00000340888 / NM_001366975.1; = p.X352_splice on NM_001039582.3) | Splice Site (SNP) | VAF 13/112 reads (12%) | called by muse, mutect2
- PRKDC | c.4196G>T p.C1399F | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- PSMD2 | c.784T>G p.F262V | Missense Mutation (SNP) | VAF 36/475 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2
- PWWP3B | c.1178G>T p.G393V | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAB40AL | c.787C>A p.P263T | Missense Mutation (SNP) | VAF 23/487 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.786); called by muse, mutect2
- RBL2 | c.1547A>T p.D516V | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2
- RFX7 | c.3945G>C p.Q1315H (on ENST00000559447 / NM_001368074.1; = p.Q1412H on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.03); called by muse, mutect2
- RNF150 | c.164C>G p.P55R | Missense Mutation (SNP) | VAF 13/203 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2
- RYR2 | c.5297C>A p.P1766H | Missense Mutation (SNP) | VAF 28/327 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2
- RYR2 | c.9587G>T p.S3196I | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.125); called by mutect2, varscan2
- RYR3 | c.130G>T p.G44W | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SDK2 | c.4979A>T p.K1660M | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- SELENON | c.1360G>T p.G454W | Missense Mutation (SNP) | VAF 17/239 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SEMA4C | c.840G>T p.K280N | Missense Mutation (SNP) | VAF 19/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SEMA7A | c.1425G>T p.R475S | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2
- SEPTIN5 | c.656A>G p.Q219R | Missense Mutation (SNP) | VAF 29/435 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.32); called by muse, mutect2
- SEPTIN9 | c.1569C>G p.I523M (on ENST00000427177 / NM_001113491.2; = p.I505M on NM_006640.4) | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SH3D21 | c.97G>T p.A33S | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- SKIDA1 | c.1932T>A p.F644L | Missense Mutation (SNP) | VAF 21/254 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2
- SLC17A4 | c.1445G>C p.R482P | Missense Mutation (SNP) | VAF 38/442 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.264); called by muse, mutect2
- SLC35G5 | c.592C>G p.L198V | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- SLC6A8 | c.875A>G p.Y292C | Missense Mutation (SNP) | VAF 31/431 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPECC1 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.044); called by muse, mutect2
- STON1 | c.1039G>C p.V347L | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- THEMIS | c.1413C>A p.D471E | Missense Mutation (SNP) | VAF 29/233 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM131 | c.160G>C p.V54L | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.023); called by muse, mutect2
- TMEM132E | c.744G>T p.K248N (on ENST00000321639; = p.K338N on NM_001304438.2) | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- TMEM176B | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TRIM56 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); called by muse, mutect2
- TRMT6 | c.1059G>T p.Q353H | Missense Mutation (SNP) | VAF 30/604 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.362); called by muse, mutect2
- TTN | c.7445A>T p.D2482V (on ENST00000591111; = p.D2436V on NM_003319.4) | Missense Mutation (SNP) | VAF 36/638 reads (6%) | PolyPhen benign (0.164); called by muse, mutect2
- TXNDC2 | c.820G>T p.V274L (on ENST00000306084 / NM_001098529.2; = p.V207L on NM_032243.6) | Missense Mutation (SNP) | VAF 25/378 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.062); called by muse, mutect2
- WDR17 | c.1924G>T p.G642* | Nonsense Mutation (SNP) | VAF 22/384 reads (6%) | called by muse, mutect2
- ZMYM4 | c.1945A>T p.S649C | Missense Mutation (SNP) | VAF 30/804 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.213); called by muse, mutect2
- ZNF729 | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 10/239 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- ADAM11 | c.1425G>A p.K475= | Silent (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- ANO5 | c.681C>T p.G227= | Silent (SNP) | VAF 28/389 reads (7%) | catalogued as rs547557493, COSV100201421; called by muse, mutect2
- APBB3 | c.6G>T p.L2= | Silent (SNP) | VAF 14/208 reads (7%) | called by muse, mutect2
- BRSK1 | c.1441C>A p.R481= | Silent (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- CNTN5 | c.825G>T p.V275= | Silent (SNP) | VAF 29/531 reads (5%) | called by muse, mutect2
- CPED1 | c.2238C>A p.T746= | Silent (SNP) | VAF 70/950 reads (7%) | catalogued as COSV60003615; called by muse, mutect2
- CXorf65 | c.42G>C p.L14= | Silent (SNP) | VAF 26/282 reads (9%) | catalogued as rs1181373087; called by muse, mutect2
- DOK3 | c.744C>A p.A248= | Silent (SNP) | VAF 23/211 reads (11%) | called by muse, mutect2, varscan2
- EZHIP | c.165G>T p.S55= | Silent (SNP) | VAF 24/374 reads (6%) | called by muse, mutect2
- FGR | c.168C>T p.F56= | Silent (SNP) | VAF 33/394 reads (8%) | called by muse, mutect2
- GPR50 | c.1296C>A p.P432= | Silent (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- HEATR6 | c.2505A>T p.S835= | Silent (SNP) | VAF 57/682 reads (8%) | called by muse, mutect2
- HEPH | c.1206T>A p.T402= (on ENST00000343002; = p.T135= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/232 reads (9%) | called by muse, mutect2
- HTATSF1 | c.1335T>A p.S445= | Silent (SNP) | VAF 22/310 reads (7%) | called by muse, mutect2
- NAP1L2 | c.837T>A p.P279= | Silent (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- NAT2 | c.198G>T p.G66= | Silent (SNP) | VAF 13/138 reads (9%) | catalogued as rs753361951; called by muse, mutect2
- NOL4 | c.966T>C p.D322= | Silent (SNP) | VAF 52/648 reads (8%) | called by muse, mutect2
- NRK | c.762C>A p.A254= | Silent (SNP) | VAF 27/422 reads (6%) | called by muse, mutect2
- NRK | c.1464T>A p.P488= | Silent (SNP) | VAF 25/304 reads (8%) | catalogued as rs369374012; called by muse, mutect2
- NWD2 | c.4176T>C p.L1392= | Silent (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- OR10J1 | c.561C>A p.S187= | Silent (SNP) | VAF 24/362 reads (7%) | catalogued as COSV71128889; called by muse, mutect2
- OR7G2 | c.351C>A p.G117= | Silent (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- OR8I2 | c.63T>G p.P21= | Silent (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2, varscan2
- PACRG | c.390A>G p.G130= | Silent (SNP) | VAF 36/466 reads (8%) | called by muse, mutect2
- PKD2L1 | c.1605C>A p.I535= | Silent (SNP) | VAF 41/502 reads (8%) | catalogued as COSV58394641; called by muse, mutect2
- PLEKHG3 | c.456G>T p.R152= (on ENST00000394691; = p.R208= on NM_001308147.2) | Silent (SNP) | VAF 17/234 reads (7%) | called by muse, mutect2
- PLOD2 | c.546A>G p.Q182= | Silent (SNP) | VAF 28/488 reads (6%) | catalogued as rs1407829114; called by muse, mutect2
- PTGIS | c.1098C>A p.A366= | Silent (SNP) | VAF 32/266 reads (12%) | called by muse, mutect2, varscan2
- RADIL | c.2751C>A p.P917= | Silent (SNP) | VAF 22/386 reads (6%) | called by muse, mutect2
- RESP18 | c.240G>A p.Q80= | Silent (SNP) | VAF 15/311 reads (5%) | called by muse, mutect2
- RYR2 | c.5298C>G p.P1766= | Silent (SNP) | VAF 26/332 reads (8%) | catalogued as COSV63704465; called by muse, mutect2
- SLC26A11 | c.657G>T p.R219= | Silent (SNP) | VAF 40/474 reads (8%) | called by muse, mutect2
- SPTA1 | c.6735C>A p.L2245= | Silent (SNP) | VAF 27/320 reads (8%) | catalogued as COSV63751787; called by muse, mutect2
- TEKT4 | c.420C>A p.T140= | Silent (SNP) | VAF 32/335 reads (10%) | called by muse, mutect2
- TIGD1 | c.1149C>T p.A383= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- TMEM132B | c.660G>T p.T220= | Silent (SNP) | VAF 33/407 reads (8%) | catalogued as COSV54751996; called by muse, mutect2
- TOR1AIP2 | c.480G>A p.E160= | Silent (SNP) | VAF 22/268 reads (8%) | called by muse, mutect2
- USH2A | c.5367A>T p.L1789= | Silent (SNP) | VAF 26/410 reads (6%) | called by muse, mutect2
- XKR6 | c.1404C>A p.T468= | Silent (SNP) | VAF 16/152 reads (11%) | called by muse, mutect2
- ZNF534 | c.633T>C p.S211= (on ENST00000332323 / NM_001143939.3; = p.S198= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/298 reads (4%) | called by muse, mutect2
- AC024940.1 | n.4728G>T | RNA (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- AC024940.1 | n.61C>A | RNA (SNP) | VAF 28/366 reads (8%) | called by muse, mutect2
- CCDC120 | c.-25G>T | 5'UTR (SNP) | VAF 14/194 reads (7%) | catalogued as rs782559146; called by muse, mutect2
- CEROX1 | n.3098C>T | RNA (SNP) | VAF 39/345 reads (11%) | catalogued as rs753663056; called by muse, mutect2, varscan2
- DENND5B | c.128-45062A>G | Intron (SNP) | VAF 28/419 reads (7%) | catalogued as rs1344740357; called by muse, mutect2
- FHL1 | c.*511C>G | 3'UTR (SNP) | VAF 19/226 reads (8%) | called by muse, mutect2
- FHL1 | c.*1084C>T | 3'UTR (SNP) | VAF 14/257 reads (5%) | called by muse, mutect2
- FRMD8P1 | n.679C>A | RNA (SNP) | VAF 29/274 reads (11%) | called by muse, mutect2, varscan2
- LCN12 | c.550+43G>T | Intron (SNP) | VAF 33/372 reads (9%) | called by muse, mutect2
- PNO1 | chr2:68157571 G>T | 5'Flank (SNP) | VAF 37/378 reads (10%) | called by muse, mutect2
- PPHLN1 | c.1126-986G>A | Intron (SNP) | VAF 56/617 reads (9%) | catalogued as rs913222770; called by muse, mutect2
- RNF5P1 | n.102T>C | RNA (SNP) | VAF 36/499 reads (7%) | called by muse, mutect2
- SMAP1 | c.664+778G>T | Intron (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
- SSPOP | n.13895G>T | RNA (SNP) | VAF 14/242 reads (6%) | catalogued as COSV65133897; called by muse, mutect2
- TAZ | c.*437G>C | 3'UTR (SNP) | VAF 32/394 reads (8%) | called by muse, mutect2
- TRPV3 | c.1503+46A>T | Intron (SNP) | VAF 15/215 reads (7%) | called by muse, mutect2
- UGT2B27P | n.1549C>A | RNA (SNP) | VAF 52/695 reads (7%) | catalogued as rs776352299; called by muse, mutect2
- WWOX | c.*65G>T | 3'UTR (SNP) | VAF 33/246 reads (13%) | called by muse, mutect2, varscan2
